Somatic mutation profile of tumor specimen 0DX8KK from CCDI case PBCRER, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.7 years (252 days).
Specimen 0DX8KK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6785335-41f6-4219-b836-ff86f1985fc5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX8JR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72ef49c3-a96a-4c67-9f00-e024aedf693a

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Missense Mutation 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD163 | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 406/1265 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs999756429; called by muse, mutect2, varscan2
- EIF5 | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 20/701 reads (3%) | SIFT tolerated (0.58); PolyPhen benign (0.014); catalogued as rs1335696514; called by muse, mutect2
- ATP2B3 | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 258/748 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- DNAH8 | c.10314T>C p.I3438= | Splice Region (SNP) | VAF 24/822 reads (3%) | called by muse, mutect2
- HK1 | c.2190C>T p.D730= | Silent (SNP) | VAF 326/923 reads (35%) | catalogued as rs754547860; called by muse, mutect2, varscan2
- PCDHGB2 | c.1995G>A p.A665= | Silent (SNP) | VAF 244/679 reads (36%) | catalogued as rs762720403; called by mutect2, varscan2
- TYROBP | c.267G>A p.S89= | Silent (SNP) | VAF 248/753 reads (33%) | catalogued as rs760509495, COSV52887249; called by muse, mutect2, varscan2
